MMRF case MMRF_2507 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/9128deb9-aaf1-44a3-a047-19d51120cc99

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.5 years (25,035 days); ISS stage: III; Days to last known disease status: 349 days; Days to last follow up: 349 days.
   Treatment given: Therapeutic agents: Bortezomib + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 162 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 28 days; Days to treatment end: 162 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 171 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 171 days; Days to treatment end: 324 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 328 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 349.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4: M Protein 4.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 159 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.84 mg/dL; Immunoglobulin G 62.7 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 1.15 g/L; Beta 2 Microglobulin 6.7 µg/mL; Lactate Dehydrogenase 3.92 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 9.6 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 132 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 1.83 mmol/L; Albumin 23 g/L; Glucose 5.17 mmol/L.
- Day 98 (ECOG 2): M Protein 3.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 196 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.64 mg/dL; Immunoglobulin G 57.9 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.66 g/L; Hemoglobin 4.84 mmol/L; Leukocytes 1.9 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.1 mmol/L; Albumin 27 g/L; Total Protein 9.5 g/dL; Glucose 4.84 mmol/L.
- Day 178 (ECOG 2): Hemoglobin 5.52 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 2.13 mmol/L; Albumin 29 g/L; Total Protein 8.4 g/dL; Glucose 5.01 mmol/L.
- Day 226 (ECOG 3): M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 64.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.313 mg/dL; Hemoglobin 5.21 mmol/L; Leukocytes 1.8 ×10⁹/L; Absolute Neutrophil 0.7 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 156 µmol/L; Blood Urea Nitrogen 13.9 mmol/L; Calcium 2.2 mmol/L; Albumin 32 g/L; Total Protein 7 g/dL; Glucose 6.71 mmol/L.
- Day 324 (ECOG 3): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 348 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.6 mg/dL; Hemoglobin 5.58 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 153 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 7.3 g/dL; Glucose 6.27 mmol/L.

Other clinical attributes
- Day -4: Weight: 62 kg; Height: 173 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Leukemia; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Child.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Bladder Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2507_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_2507_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
